Somatic mutation profile of tumor specimen TCGA-FD-A6TD-01A (aliquot TCGA-FD-A6TD-01A-51D-A339-08) from TCGA case TCGA-FD-A6TD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 77.6 years (28,328 days).
Specimen TCGA-FD-A6TD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) baa003f0-c9b7-4247-9fba-19f54b07ca26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A6TD-10A (Blood Derived Normal), aliquot TCGA-FD-A6TD-10A-21D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2e83d4b-a6ca-424c-a869-2d086351b243

The open-access MAF lists 143 somatic variants for this specimen: 104 protein-altering or splice-affecting, 37 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 37, Nonsense Mutation 8, Frame Shift Ins 4, Frame Shift Del 3, Intron 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND1 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119102, COSV57119569, COSV57120578; called by muse, mutect2, varscan2
- CIC | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50554672, COSV50623937; called by muse, mutect2, varscan2
- TP53 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52678014, COSV52747111, COSV52839912, COSV53772942; called by muse, mutect2, varscan2
- TP53 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52660939, COSV52789715, COSV53470581; called by muse, mutect2, varscan2
- A2M | c.3649C>G p.L1217V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV100588505; called by muse, mutect2, varscan2
- ACTR1A | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs1313811564, COSV64023833; called by muse, mutect2, varscan2
- ADAMTS4 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs749313727, COSV63488238; called by muse, mutect2, varscan2
- ADCY10 | c.3043C>A p.P1015T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV63242705; called by muse, mutect2, varscan2
- ADCY8 | c.3058G>C p.E1020Q | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV53917003; called by muse, mutect2, varscan2
- AGBL5 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV59937248; called by muse, varscan2
- AGBL5 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59937265; called by muse, varscan2
- AHNAK2 | c.2108C>G p.P703R | Missense Mutation (SNP) | VAF 72/271 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV60921987, COSV60930429; called by muse, mutect2, varscan2
- B3GNT2 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57345236; called by muse, mutect2, varscan2
- BIRC6 | c.13900C>G p.Q4634E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.921); catalogued as COSV70202793; called by muse, mutect2, varscan2
- BMP1 | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201664686, COSV60532838; called by muse, mutect2, varscan2
- CACUL1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV64968904; called by muse, mutect2, varscan2
- CBX4 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53966377; called by muse, mutect2
- CCDC9B | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV66874899, COSV66875744; called by muse, mutect2, varscan2
- CDH12 | c.2273C>G p.T758S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV66424616; called by muse, mutect2, varscan2
- CDH18 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs375736859; called by muse, mutect2, varscan2
- CNST | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.103); catalogued as rs1192963708, COSV63622143; called by muse, mutect2, varscan2
- COL2A1 | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756155678, COSV61532352; called by muse, mutect2, varscan2
- CPA4 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1184192184, COSV55984193; called by muse, mutect2, varscan2
- CPE | c.470T>A p.L157Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV68581469; called by muse, mutect2, varscan2
- CUL1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV57388811; called by muse, mutect2, varscan2
- EFCAB7 | c.40C>G p.Q14E | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV52134119; called by muse, mutect2, varscan2
- FAAH | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV54545032; called by muse, varscan2
- FAAH | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54545043; called by muse, varscan2
- FANCL | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs1389670408, COSV52076070; called by muse, mutect2, varscan2
- FANCM | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs112784867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs567450408, COSV58560005; called by muse, mutect2, varscan2
- GCNT4 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as COSV59281273; called by muse, mutect2, varscan2
- GPANK1 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | catalogued as COSV100788978; called by muse, mutect2, varscan2
- GPRASP1 | c.3505C>T p.P1169S | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64356078; called by muse, mutect2, varscan2
- GRID2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV56231855; called by muse, mutect2, varscan2
- GTF2F1 | c.234G>C p.E78D | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV101081435, COSV66726425; called by muse, mutect2, varscan2
- GZF1 | c.1808G>A p.W603* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100582404; called by muse, mutect2, varscan2
- HECTD4 | c.4484C>G p.S1495C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as COSV61180519; called by muse, mutect2
- HECTD4 | c.3856C>G p.L1286V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV61180528; called by muse, mutect2, varscan2
- HELZ | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV62379562; called by muse, mutect2, varscan2
- IGSF10 | c.3532A>G p.T1178A | Missense Mutation (SNP) | VAF 76/263 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56788431; called by muse, mutect2, varscan2
- ITPR1 | c.7069C>G p.L2357V (on ENST00000354582; = p.L2302V on NM_002222.7) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV56992314; called by muse, mutect2, varscan2
- KCND2 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58591936; called by muse, mutect2, varscan2
- KDM4C | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67188959; called by muse, mutect2, varscan2
- KIAA0895L | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs752665223, COSV99220418; called by muse, varscan2
- KIAA1755 | c.1543G>A p.G515R | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV54078549; called by muse, mutect2, varscan2
- KLF10 | c.137T>C p.M46T | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs753790380, COSV53436062; called by muse, mutect2, varscan2
- KLHDC8B | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as COSV60412247; called by muse, mutect2, varscan2
- KLHL11 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); catalogued as rs782076593, COSV59862534; called by muse, mutect2, varscan2
- LIFR | c.2296G>A p.G766R | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs760139333, COSV54694685; called by muse, mutect2, varscan2
- LUZP1 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as rs745888186, COSV56503245; called by muse, mutect2, varscan2
- MAP9 | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV60905522, COSV60906529; called by muse, varscan2
- MARS2 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs898307831, COSV56571838; called by muse, mutect2, varscan2
- MCM7 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 157/468 reads (34%) | catalogued as rs758325786, COSV57993915; called by muse, mutect2, varscan2
- MRPS22 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs774588858, COSV60348996, COSV60350702; called by muse, mutect2, varscan2
- MTX2 | c.741G>C p.R247S | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV50888746; called by muse, mutect2, varscan2
- MUC17 | c.8476delinsTA p.E2826* | Nonsense Mutation (INS) | VAF 79/512 reads (15%) | catalogued as COSV60295694; called by mutect2*, pindel, varscan2*
- NKAP | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100538214, COSV57630731; called by muse, mutect2, varscan2
- NSD1 | c.3686C>T p.S1229L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.005); catalogued as COSV61779636; called by muse, mutect2, varscan2
- OR5I1 | c.705del p.R236Gfs*12 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as COSV56886514; called by mutect2, varscan2
- OVCH1 | c.2837T>A p.V946E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.848); catalogued as COSV58965562; called by muse, mutect2, varscan2
- PENK | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs143937196; called by muse, mutect2, varscan2
- PHF1 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs866890619, COSV65703099; called by muse, mutect2, varscan2
- PIK3CA | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as rs1433512757, COSV55955047; called by muse, mutect2
- POC1A | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs771448219, COSV56592446; called by muse, varscan2
- PRDM4 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV99946402; called by mutect2, varscan2
- PRPS2 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 113/194 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66179848; called by muse, mutect2, varscan2
- PSMB8 | c.646C>T p.R216W (on ENST00000374882 / NM_148919.4; = p.R212W on NM_004159.5) | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as rs146956608; called by muse, mutect2, varscan2
- PSMD2 | c.2275C>G p.L759V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV59530685; called by muse, mutect2, varscan2
- RHBDD2 | c.628G>C p.V210L | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as COSV50087611; called by muse, mutect2
- RORC | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV59094252; called by muse, mutect2, varscan2
- RUSC2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV63429478; called by muse, mutect2, varscan2
- RYR2 | c.7570G>A p.V2524I | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.266); catalogued as rs934248102, COSV63687294; called by muse, mutect2, varscan2
- RYR2 | c.10625C>T p.S3542L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV100767208, COSV63698497; called by muse, mutect2, varscan2
- SCAF4 | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV54585511; called by muse, mutect2, varscan2
- SCN2A | c.2863G>A p.G955S | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV51848349; called by muse, mutect2, varscan2
- SERPINA12 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as COSV57944811; called by muse, mutect2, varscan2
- SESN3 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53586139; called by muse, mutect2, varscan2
- SLU7 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147723488, COSV99775851; called by muse, mutect2, varscan2
- SPRR1B | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs751942144, COSV61067467; called by muse, mutect2, varscan2
- SYNE2 | c.11720C>T p.S3907L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV59949078; called by muse, mutect2, varscan2
- TANK | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52046406; called by muse, mutect2, varscan2
- TEX15 | c.1216G>C p.E406Q (on ENST00000256246; = p.E789Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.646); catalogued as COSV56349730; called by muse, mutect2, varscan2
- TFAP2B | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs759054590, COSV53829387; called by muse, mutect2
- THYN1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757141767, COSV55540506; called by muse, mutect2, varscan2
- TLK2 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV58303057; called by muse, mutect2
- TLL1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV50304774, COSV50338841; called by muse, mutect2, varscan2
- TMEM132B | c.2500C>T p.R834C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54760830; called by muse, mutect2, varscan2
- TMEM151A | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV59174344; called by muse, mutect2, varscan2
- TMEM67 | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100018764; called by muse, mutect2, varscan2
- TOB2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100548370; called by muse, mutect2, varscan2
- TSC2 | c.2909C>G p.S970C | Missense Mutation (SNP) | VAF 82/139 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs758447107, COSV54767889; called by muse, mutect2, varscan2
- UBE2M | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV53397401; called by muse, mutect2, varscan2
- UPF1 | c.2914del p.Q972Rfs*8 (on ENST00000599848 / NM_001297549.2; = p.Q961Rfs*8 on NM_002911.4) | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as COSV99439544, COSV99440655; called by mutect2, pindel, varscan2
- USP7 | c.2785G>A p.V929M | Missense Mutation (SNP) | VAF 70/610 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs368894909, COSV100784074, COSV61218196; called by muse, mutect2, varscan2
- VAC14 | c.1830G>C p.K610N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as COSV55755533; called by muse, mutect2, varscan2
- WASHC2A | c.4026G>C p.*1342Yext*53 | Nonstop Mutation (SNP) | VAF 10/111 reads (9%) | catalogued as COSV99254501; called by muse, mutect2
- ZNF232 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV51504243; called by muse, mutect2, varscan2
- ZNF586 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 41/248 reads (17%) | catalogued as COSV101656724; called by muse, mutect2, varscan2
- ACTL9 | c.927dup p.L310Afs*120 | Frame Shift Ins (INS) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- MUC17 | c.8475dup p.E2826* | Frame Shift Ins (INS) | VAF 132/448 reads (29%) | called by mutect2, varscan2
- NOP9 | c.274_277del p.E92* | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by pindel, varscan2
- RB1 | c.2329_2330dup p.T778Lfs*33 | Frame Shift Ins (INS) | VAF 49/177 reads (28%) | called by mutect2, pindel, varscan2
- RPL35 | c.62_66dup p.D23Wfs*4 | Frame Shift Ins (INS) | VAF 19/110 reads (17%) | called by pindel, varscan2*
- ADCY3 | c.3303G>T p.V1101= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99567801; called by muse, mutect2
- AFM | c.1386T>C p.C462= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV56921149; called by muse, mutect2, varscan2
- AGAP4 | c.1305G>A p.L435= | Silent (SNP) | VAF 67/178 reads (38%) | catalogued as rs782427868, COSV101432620; called by muse, mutect2, varscan2
- ATP7A | c.1497C>T p.C499= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs782495317, COSV58449796; called by muse, mutect2, varscan2
- BTNL2 | c.54C>T p.F18= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV66630357; called by muse, mutect2, varscan2
- C1QTNF1 | c.585C>T p.F195= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as rs997154592, COSV59260966; called by muse, mutect2
- CABP5 | c.477C>T p.D159= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs758495669, COSV53152802; called by muse, mutect2, varscan2
- CDH9 | c.1611C>T p.F537= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV50292477; called by muse, mutect2, varscan2
- CELA2B | c.717G>A p.S239= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs1035111607, COSV61602012; called by muse, mutect2, varscan2
- CHGA | c.156C>G p.V52= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV53663942; called by muse, mutect2, varscan2
- CNTN6 | c.495C>T p.Y165= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs114806249; called by muse, mutect2, varscan2
- COL6A3 | c.2814T>C p.D938= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs1236315058, COSV55098455; called by muse, mutect2, varscan2
- DSEL | c.1386G>A p.Q462= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV59493060; called by muse, mutect2, varscan2
- FAM53A | c.1044C>T p.V348= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV57402399; called by muse, mutect2, varscan2
- FAM76A | c.745T>C p.L249= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs758231941, COSV50549414; called by muse, mutect2, varscan2
- GPN2 | c.306C>A p.L102= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV64652370; called by muse, mutect2, varscan2
- HAUS5 | c.1209C>T p.L403= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV52548826; called by muse, mutect2, varscan2
- HIVEP3 | c.2544C>T p.V848= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as COSV56018946; called by muse, mutect2, varscan2
- INTS1 | c.1350C>G p.L450= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs759733963, COSV67178495; called by muse, mutect2, varscan2
- MAP2 | c.3627T>C p.D1209= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV52299169; called by muse, mutect2, varscan2
- NRROS | c.1758G>A p.L586= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs1319312390, COSV60746790; called by muse, mutect2, varscan2
- RGS22 | c.1641C>G p.L547= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV62661982; called by muse, mutect2, varscan2
- SCN1A | c.2979C>T p.S993= (on ENST00000303395 / NM_001202435.3; = p.S982= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as CM113310, COSV57678555; called by muse, mutect2, varscan2
- SEZ6L | c.210C>A p.P70= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV50671185, COSV99961135; called by muse, mutect2, varscan2
- SLC43A3 | c.654C>T p.P218= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV61450837; called by muse, mutect2, varscan2
- SLU7 | c.906G>A p.K302= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV51789029; called by muse, mutect2, varscan2
- STAU2 | c.177G>A p.K59= (on ENST00000524300 / NM_001164380.2; = p.K27= on NM_014393.2) | Silent (SNP) | VAF 54/214 reads (25%) | catalogued as COSV62477373; called by muse, mutect2, varscan2
- TAS2R39 | c.666C>T p.I222= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV71470941; called by muse, mutect2, varscan2
- TCF7L2 | c.1527G>A p.S509= (on ENST00000355995 / NM_001367943.1; = p.S486= on NM_030756.5) | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs760999129, COSV53342849, COSV99525614; called by muse, mutect2
- TFAP2C | c.840G>A p.E280= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV52372272; called by muse, mutect2, varscan2
- TMEM150B | c.585C>G p.L195= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV58594101; called by muse, mutect2, varscan2
- TXNDC16 | c.2361C>T p.V787= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV55985800; called by muse, mutect2, varscan2
- UNC13A | c.2157C>T p.L719= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99407382; called by muse, mutect2
- VGF | c.1410C>T p.V470= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV50801743; called by muse, varscan2
- ZNF320 | c.387G>A p.R129= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as rs776479114, COSV67088540; called by muse, mutect2, varscan2
- ZNF493 | c.1080C>G p.P360= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV62750979; called by muse, varscan2
- ZNF619 | c.324G>A p.L108= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV59030593; called by muse, mutect2, varscan2
- DIP2C | c.157+1672C>T | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs1016792890; called by muse, mutect2
- TMPRSS11F | c.1015+1857G>T | Intron (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100678248, COSV62467317; called by muse, mutect2, varscan2
